Somatic mutation profile of tumor specimen 0DPYE7 from CCDI case PBCEKG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Pineal gland; Age at diagnosis: 17.9 years (6,523 days).
Specimen 0DPYE7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac43608f-26e1-4769-88a6-1ddbf924bb75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPYDA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40be35d1-eeab-4ac6-b557-23de6fb95672

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCIN | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 46/951 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs867238115; called by muse, mutect2
- MIB1 | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 296/680 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs759225220; called by muse, mutect2, varscan2
- NRG3 | c.1607C>G p.S536C (on ENST00000404547 / NM_001370084.1; = p.S315C on NM_001165973.1) | Missense Mutation (SNP) | VAF 33/506 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV64572347; called by muse, mutect2
- BLVRA | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 82/561 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX3X | c.1240A>G p.I414V (on ENST00000399959; = p.I415V on NM_001356.5) | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MATR3 | c.1779-2del p.X593_splice | Splice Site (DEL) | VAF 206/650 reads (32%) | called by pindel, varscan2
- TAF1B | c.1422T>A p.S474R | Missense Mutation (SNP) | VAF 368/943 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZSWIM4 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZSWIM6 | c.2272A>G p.I758V | Missense Mutation (SNP) | VAF 100/639 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADCY7 | c.1605C>T p.S535= | Silent (SNP) | VAF 21/459 reads (5%) | catalogued as rs1332554116; called by muse, mutect2
- HIPK2 | c.1299G>A p.R433= | Silent (SNP) | VAF 66/1036 reads (6%) | catalogued as COSV99065683; called by muse, mutect2
- MINDY2 | c.1725T>A p.S575= | Silent (SNP) | VAF 26/361 reads (7%) | called by muse, mutect2
- PCNX2 | c.264A>T p.G88= | Silent (SNP) | VAF 78/936 reads (8%) | called by muse, mutect2
- TAS2R5 | c.843G>A p.Q281= | Silent (SNP) | VAF 29/846 reads (3%) | called by muse, mutect2
- SLC51A | c.522-16C>A | Intron (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
